Gene-level copy-number profile of tumor specimen TCGA-60-2711-01A from TCGA case TCGA-60-2711, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.8 years (23,651 days).
Specimen TCGA-60-2711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b99e81fb-0a6c-4ace-99a6-018c26032f6c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2711-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 848 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27ab9632-aa58-47f3-ac5c-1d91eed5e7a1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 597; copy number 2: 15,450; copy number 3: 24,189; copy number 4: 14,329; copy number 5: 4,137; copy number 6: 307; copy number 7: 200; copy number 8: 6; copy number 9: 78; copy number 12: 10; copy number 13: 80; copy number 14: 130; copy number 16: 3; copy number 17: 123; copy number 20: 44; copy number 28: 1; copy number 40: 41; copy number 42: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2711-01A-01D-0844-01): tumor purity 0.65, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 766 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,304,294–40,517,174, 50 genes, copy number 42: HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2.
- chr3:139,837,220–149,503,394, 144 genes, copy number 7 (broad region; genes not listed).
- chr3:149,525,631–149,525,726, 1 gene, copy number 7: RNU6-1098P.
- chr3:150,602,875–153,377,562, 52 genes, copy number 7: SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, AC011317.1, SIAH2, SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1, MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1, AC092924.1, AC092924.2, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2.
- chr3:153,431,856–153,607,479, 3 genes, copy number 7: LINC02877, RNU6-901P, Y_RNA.
- chr3:160,677,160–160,755,142, 3 genes, copy number 16: ARL14, SNORA72, AC069224.1.
- chr3:161,083,883–161,105,411, 1 gene, copy number 28: B3GALNT1.
- chr3:162,601,627–163,479,500, 6 genes, copy number 8: AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P.
- chr3:166,160,021–185,938,103, 345 genes, copy number 9–40 (broad region; genes not listed).
- chr3:190,514,051–194,826,008, 76 genes, copy number 14–20 (within-gene range 4–20) (broad region; genes not listed).
- chr3:196,027,183–198,222,513, 85 genes, copy number 17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 597. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
